CCDI case PBBZPT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Small intestine.
https://portal.gdc.cancer.gov/cases/f689a1be-2eab-4de7-b74e-ea15062a8322

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Signet ring cell carcinoma: ICD-O-3 morphology code: 8490/3; Tissue or organ of origin: Small intestine, NOS; Age at diagnosis: 16.4 years (6,008 days).

Biospecimens (3 samples)
- Sample 0DM1JD: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM1JL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM1K9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
